Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1D4, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1D4-01A (Primary Tumor).

1CB-0-3
Adenocarcinoma, NOS 8/40/3

Site: Cecum S18.0

1/2/11
fw

(First Tumor)

Tumor Site:	Cecum Proximal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☐ No ☐ Yes ☒ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	None
Crohn's like reaction	☒ None ☐ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☐ No ☒ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☐ Yes ☒ Yes (Focal) ☐ Unknown
TIL Cells / HPF	2.8
Pathologist Comment:	+/- on mutator phenotype

Criticla	Yes	No
HIP/IA Discrepancy		

Source: NCI Genomic Data Commons file 0bb19aad-6073-4a46-81b3-9629f7294d34 (TCGA-DM-A1D4.98310DA6-E41D-4725-A634-D17B88A7CFE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).